CGCI case BLGSP-71-06-00254 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/681ff2e8-6073-4dab-a398-1f2203c2d7f5

Demographics
Sex at birth: male; Race: black or african american; Age at index: 6 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Abdomen, NOS; Classification of tumor: primary; Age at diagnosis: 6.2 years (2,253 days); Year of diagnosis: 2015; Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 382 days (1.0 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Endemic; Max tumor bulk site: Other; Sites of involvement: Kidney, NOS / Stomach.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Axillary; Tumor largest dimension diameter: 15 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: COP; Days to treatment start: 0 days; Days to treatment end: 0 days; Number of cycles: 1.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days; Days to treatment end: 0 days; Number of cycles: 1.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Adjuvant; Regimen or line of therapy: CHOP; Days to treatment start: 11 days; Days to treatment end: 113 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Vincristine; Treatment intent type: Adjuvant; Days to treatment start: 11 days; Days to treatment end: 113 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 20; ECOG performance status: 4.
- Days to follow up: 5 days; Disease response: With Tumor.
- Days to follow up: 382 days (1.0 years); Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 1198 [Blood test normal range upper: 340].

Other clinical attributes
- Day 0: Weight: 22 kg; Height: 110 cm; BMI: 18.2.

Biospecimens (3 samples)
- Sample BLGSP-71-06-00254-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Abdomen; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Needle Biopsy; Tissue collection type: Prospective.
- Sample BLGSP-71-06-00254-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-06-00254-12A: Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Days to sample procurement: 5 days; Method of sample procurement: Other; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Days from index date to last known alive: 5; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 2; Extranodal involvment other: Epigastrium; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Tru-cut biopsy; Lymph nodes examined: No.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 1198; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Treatments, Treatment 1: Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 6.
- Treatments, Treatment 2: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 1.
